Somatic mutation profile of tumor specimen TARGET-40-PAKFVX-01A (aliquot TARGET-40-PAKFVX-01A-01D) from TARGET case TARGET-40-PAKFVX, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 14.8 years (5,407 days).
Specimen TARGET-40-PAKFVX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a800fadd-3810-45d3-9b7b-deebd727b34a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-PAKFVX-10A (Blood Derived Normal), aliquot TARGET-40-PAKFVX-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0a2d520b-0fc9-4026-b36d-89a1fbdb8e99

The open-access MAF lists 85 somatic variants for this specimen: 42 protein-altering or splice-affecting, 17 silent, 26 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 17, Intron 8, RNA 7, 3'UTR 6, Nonsense Mutation 4, 5'UTR 3, In Frame Del 2, 3'Flank 2, Frame Shift Del 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CIT | c.1164del p.F388Lfs*17 | Frame Shift Del (DEL) | VAF 34/89 reads (38%) | catalogued as COSV55868403; called by mutect2, pindel, varscan2
- CLGN | c.1784G>A p.G595E | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.762); catalogued as rs767973851, COSV57776932; called by muse, mutect2, varscan2
- CSMD3 | c.4798C>T p.L1600F (on ENST00000297405 / NM_001363185.1; = p.L1496F on NM_052900.3) | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.261); catalogued as COSV52158139, COSV99835789; called by muse, mutect2, varscan2
- FAM43A | c.258C>A p.D86E | Missense Mutation (SNP) | VAF 59/139 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1297532827; called by muse, mutect2, varscan2
- FANCA | c.3251G>A p.R1084H | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs752642945; called by muse, mutect2, varscan2
- GK5 | c.461G>A p.R154Q | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.273); catalogued as rs1379885995, COSV101242027; called by mutect2, varscan2
- OR10G9 | c.768C>A p.F256L | Missense Mutation (SNP) | VAF 56/145 reads (39%) | SIFT tolerated (0.51); PolyPhen benign (0.096); catalogued as COSV66685830; called by muse, mutect2, varscan2
- PPP1R32 | c.446G>A p.R149K | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV58546051; called by muse, mutect2, varscan2
- ADGRF5 | c.3080T>C p.L1027S | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ASXL3 | c.2560G>T p.E854* | Nonsense Mutation (SNP) | VAF 26/69 reads (38%) | called by muse, mutect2, varscan2
- CCDC102B | c.584C>A p.T195K | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT tolerated (0.89); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- CCDC15 | c.217_231del p.L73_Q77del | In Frame Del (DEL) | VAF 4/12 reads (33%) | called by mutect2, varscan2
- CCDC185 | c.852G>A p.W284* | Nonsense Mutation (SNP) | VAF 8/20 reads (40%) | called by muse, mutect2, varscan2
- COMP | c.983G>T p.C328F | Missense Mutation (SNP) | VAF 65/181 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CYP2C18 | c.637A>G p.I213V | Missense Mutation (SNP) | VAF 24/29 reads (83%) | SIFT tolerated (0.31); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DACH1 | c.1270C>T p.L424F | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.689); called by muse, mutect2, varscan2
- DST | c.12064A>C p.T4022P (on ENST00000361203 / NM_001374722.1; = p.T1610P on NM_015548.5) | Missense Mutation (SNP) | VAF 40/124 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.522); called by muse, mutect2, varscan2
- FCGBP | c.6479T>C p.L2160P | Missense Mutation (SNP) | VAF 42/200 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FLT3 | c.892T>G p.F298V | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- FNDC1 | c.593A>G p.Y198C | Missense Mutation (SNP) | VAF 63/260 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- GABRR3 | c.1064C>T p.T355I | Missense Mutation (SNP) | VAF 110/298 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- GALNT16 | c.1046A>C p.K349T | Missense Mutation (SNP) | VAF 43/158 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GPR137 | c.647G>A p.C216Y | Missense Mutation (SNP) | VAF 40/116 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GPR85 | c.53T>C p.L18P | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.37); PolyPhen benign (0.274); called by muse, mutect2
- GREB1 | c.2365G>A p.D789N | Missense Mutation (SNP) | VAF 55/341 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.234); called by muse, mutect2, varscan2
- GRM5 | c.167A>C p.K56T | Missense Mutation (SNP) | VAF 51/121 reads (42%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- HELZ2 | c.223C>T p.P75S | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0.003); called by muse, mutect2
- HYDIN | c.10429G>T p.V3477L | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); called by muse, mutect2, varscan2
- ITGAL | c.2414T>C p.L805P | Missense Mutation (SNP) | VAF 90/226 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); called by muse, mutect2, varscan2
- LAMA2 | c.5794A>G p.K1932E | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- LPIN1 | c.2641G>A p.E881K | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- NBAS | c.6781G>T p.E2261* | Nonsense Mutation (SNP) | VAF 26/188 reads (14%) | called by muse, mutect2, varscan2
- NCBP1 | c.1782G>C p.W594C | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NEFM | c.1286C>A p.P429Q | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- NOSIP | c.303G>C p.E101D | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- NRXN3 | c.556C>A p.P186T | Missense Mutation (SNP) | VAF 42/161 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PARD3 | c.188_202del p.D63_D67del | In Frame Del (DEL) | VAF 10/64 reads (16%) | called by pindel, varscan2
- PCDHGC3 | c.5T>G p.V2G | Missense Mutation (SNP) | VAF 31/133 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- PKP3 | c.2374G>T p.E792* | Nonsense Mutation (SNP) | VAF 28/174 reads (16%) | called by muse, varscan2
- SLC4A5 | c.3321A>G p.I1107M | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- SLC6A11 | c.894C>A p.V298= | Splice Region (SNP) | VAF 27/95 reads (28%) | called by muse, mutect2, varscan2
- SOS2 | c.1739_1740del p.S580* | Frame Shift Del (DEL) | VAF 24/72 reads (33%) | called by pindel, varscan2
- ACOT12 | c.138T>C p.H46= | Silent (SNP) | VAF 12/39 reads (31%) | called by muse, mutect2, varscan2
- CCNT1 | c.1236C>T p.A412= | Silent (SNP) | VAF 89/167 reads (53%) | called by muse, mutect2, varscan2
- CEBPZ | c.375T>C p.N125= | Silent (SNP) | VAF 15/74 reads (20%) | catalogued as rs763832876; called by muse, mutect2
- DCAF5 | c.1332C>G p.L444= | Silent (SNP) | VAF 39/157 reads (25%) | called by muse, mutect2, varscan2
- DNAH2 | c.7824C>A p.T2608= | Silent (SNP) | VAF 35/92 reads (38%) | catalogued as COSV66723779; called by muse, mutect2, varscan2
- GLMN | c.336G>A p.E112= | Silent (SNP) | VAF 5/29 reads (17%) | called by muse, mutect2, varscan2
- GPR50 | c.1776A>G p.V592= | Silent (SNP) | VAF 76/105 reads (72%) | called by muse, mutect2, varscan2
- IGHM | c.507A>G p.K169= | Silent (SNP) | VAF 43/227 reads (19%) | called by muse, mutect2, varscan2
- MUC16 | c.2166C>A p.T722= | Silent (SNP) | VAF 99/249 reads (40%) | called by muse, mutect2, varscan2
- OR51M1 | c.525G>A p.L175= | Silent (SNP) | VAF 128/958 reads (13%) | called by muse, mutect2, varscan2
- PATL1 | c.1365G>A p.K455= | Silent (SNP) | VAF 47/190 reads (25%) | called by muse, varscan2
- PATL1 | c.1251G>A p.Q417= | Silent (SNP) | VAF 25/103 reads (24%) | called by muse, mutect2, varscan2
- PATL1 | c.594G>A p.Q198= | Silent (SNP) | VAF 36/160 reads (23%) | catalogued as rs765290536; called by muse, varscan2
- TAL1 | c.639G>T p.L213= | Silent (SNP) | VAF 26/141 reads (18%) | called by muse, mutect2, varscan2
- TMEM63C | c.1590C>T p.S530= | Silent (SNP) | VAF 29/101 reads (29%) | catalogued as COSV100029425; called by muse, mutect2, varscan2
- TSHZ3 | c.676C>T p.L226= | Silent (SNP) | VAF 76/3118 reads (2%) | called by muse, mutect2
- ZNF665 | c.711T>C p.N237= (on ENST00000600412; = p.N302= on NM_024733.5 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 44/107 reads (41%) | called by muse, mutect2, varscan2
- AC025538.1 | n.536C>T | RNA (SNP) | VAF 8/46 reads (17%) | called by muse, mutect2, varscan2
- ARHGEF11 | c.4511-95G>T | Intron (SNP) | VAF 29/133 reads (22%) | called by muse, mutect2, varscan2
- ARHGEF11 | c.4511-96A>G | Intron (SNP) | VAF 28/130 reads (22%) | called by muse, mutect2, varscan2
- ARMC8 | c.*16G>A | 3'UTR (SNP) | VAF 62/190 reads (33%) | catalogued as rs370447531; called by muse, mutect2, varscan2
- CASR | c.1378-6169G>T | Intron (SNP) | VAF 38/168 reads (23%) | catalogued as CM165782; called by muse, varscan2
- CLCA2 | c.-56C>T | 5'UTR (SNP) | VAF 11/60 reads (18%) | called by muse, mutect2
- FKBP1C | c.*57G>T | 3'UTR (SNP) | VAF 28/193 reads (15%) | called by muse, mutect2
- IL1RL1 | c.610+417G>T | Intron (SNP) | VAF 3/13 reads (23%) | called by muse, mutect2
- ISM2 | c.*16A>G | 3'UTR (SNP) | VAF 68/283 reads (24%) | called by muse, mutect2, varscan2
- KLF4 | c.*7_*24del | 3'UTR (DEL) | VAF 23/138 reads (17%) | called by mutect2, pindel, varscan2
- MYF6 | c.*6C>A | 3'UTR (SNP) | VAF 22/90 reads (24%) | called by muse, mutect2, varscan2
- NEU3 | c.306+86C>T | Intron (SNP) | VAF 35/107 reads (33%) | called by muse, mutect2, varscan2
- OR4A13P | n.750T>C | RNA (SNP) | VAF 66/83 reads (80%) | called by muse, mutect2, varscan2
- OR4N1P | n.634G>A | RNA (SNP) | VAF 28/126 reads (22%) | called by muse, mutect2, varscan2
- OR52A4P | chr11:5120670 T>C | 3'Flank (SNP) | VAF 12/81 reads (15%) | catalogued as rs748912019; called by mutect2, varscan2
- PEAK1 | c.*138A>T | 3'UTR (SNP) | VAF 9/25 reads (36%) | called by muse, mutect2
- PKD1P2 | n.3092C>T | RNA (SNP) | VAF 7/25 reads (28%) | called by mutect2, varscan2
- PKP3 | c.2359-64G>T | Intron (SNP) | VAF 33/146 reads (23%) | called by muse, varscan2
- RSPRY1 | c.350+55A>T | Intron (SNP) | VAF 6/18 reads (33%) | called by muse, mutect2
- SLAMF1 | c.-31G>T | 5'UTR (SNP) | VAF 8/34 reads (24%) | called by muse, mutect2
- SSPOP | n.14153G>A | RNA (SNP) | VAF 20/60 reads (33%) | catalogued as rs551457534, COSV65130992; called by muse, varscan2
- SSPOP | n.14676G>T | RNA (SNP) | VAF 30/122 reads (25%) | catalogued as COSV65128323; called by muse, mutect2, varscan2
- TINAG | c.-20C>T | 5'UTR (SNP) | VAF 8/30 reads (27%) | catalogued as COSV99448114; called by muse, mutect2, varscan2
- ZDHHC3 | c.306+495T>C | Intron (SNP) | VAF 15/34 reads (44%) | called by muse, mutect2, varscan2
- ZNF180 | chr19:44472308 G>T | 3'Flank (SNP) | VAF 29/81 reads (36%) | called by muse, mutect2, varscan2
- ZNF355P | n.1210A>T | RNA (SNP) | VAF 10/29 reads (34%) | called by muse, mutect2, varscan2
